Somatic mutation profile of tumor specimen TARGET-10-PANWES-09A (aliquot TARGET-10-PANWES-09A-01D) from TARGET case TARGET-10-PANWES, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,097 days).
Specimen TARGET-10-PANWES-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) faf75bc0-3ab9-4b71-9f3a-76f26b42cd5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PANWES-10A (Blood Derived Normal), aliquot TARGET-10-PANWES-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e860fb8a-0975-4e71-b2a1-4aed8372671f

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 8, Frame Shift Del 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- OTC | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 48/173 reads (28%) | catalogued as rs67960011, CM062996, CM890089, COSV50000229; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MUC16 | c.26639C>T p.P8880L | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.053); catalogued as rs772533073; called by muse, mutect2, varscan2
- ZBTB5 | c.460G>T p.V154L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100312788; called by muse, mutect2
- C1orf21 | c.241G>A p.G81R | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- CALHM3 | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CRTC3 | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.167); called by muse, mutect2
- HOMEZ | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- INTS8 | c.1969C>A p.Q657K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.954); called by muse, mutect2
- ITGA2 | c.1817G>A p.G606E | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- OR4K17 | c.716C>A p.T239N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PLEKHG7 | c.356C>A p.A119D | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.75); called by muse, mutect2
- SETX | c.3128G>T p.R1043M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2
- TENM3 | c.4094T>A p.V1365D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, varscan2
- TNPO1 | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRGV3 | c.349_352delinsCTG p.D117Lfs*? | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by pindel, varscan2*
- TRGV5 | c.349_352delinsCTG p.D117Lfs*? | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by pindel, varscan2*
- ZNF711 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- AC006059.2 | c.993G>A p.S331= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs1321173073; called by muse, mutect2
- CACNA1E | c.3780C>G p.L1260= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- ELOA2 | c.1245C>T p.N415= | Silent (SNP) | VAF 60/135 reads (44%) | catalogued as rs767658717; called by muse, mutect2, varscan2
- FAM133A | c.672G>A p.K224= | Silent (SNP) | VAF 23/98 reads (23%) | catalogued as rs1191691394; called by muse, mutect2, varscan2
- HOMEZ | c.102C>A p.L34= | Silent (SNP) | VAF 16/30 reads (53%) | called by mutect2, varscan2
- PHEX | c.1476C>G p.L492= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2, varscan2
- SLC3A1 | c.1050C>T p.F350= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as rs1376297101; called by muse, mutect2, varscan2
- STAB2 | c.4167C>T p.G1389= | Silent (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- DDX3X | c.1022+112C>T | Intron (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- EPB41L1 | c.1669-2590C>A | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
